Surgical pathology report (de-identified scan), TCGA case TCGA-EE-A29M, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Sydney, specimen TCGA-EE-A29M-06A (Metastatic).

[page 1 of 2]
DOB/Age/Sex:
Location:
Requested by:
Requested on:
Specimen Rcvd:
Accession No.:
Series to:

HISTOPATHOLOGY REPORT

CLINICAL DETAILS

(L) Lymph node dissection axilla. History of melanoma (L) elbow.

MACROSCOPIC DESCRIPTION

(Dr

Two specimens received.

1. "LEFT AXILLARY CONTENTS". The specimen is a piece of fibro fatty tissue with attached muscle. The fibro fatty tissue is 90 x 75 x 30mm and the attached muscle is 45 x 45 x 20mm. A large node 45 x 30 x 30mm is identified. Half of the largest mass was taken for tumour banking. 25 lymph nodes are identified.

- A. One section from the largest node.
- B. One bisected node.
- C. One bisected node.
- D & E. One node.
- F. One bisected node.
- G. One bisected node.
- H. Four nodes.
- J. Four nodes.
- K. Four nodes.
- L. One bisected node.
- M. One bisected node.
- N. One bisected node.
- P. Three nodes.
- Q. Three nodes.

ICD-0-3

Melanoma, NOS 8720/3

Site: lymph node, Axillary

C77-3

hw 6/2/11

2. "APICAL NODE LEFT AXILLA". Three pieces of fibro fatty tissue, the largest piece is 10mm across. The smallest piece is 4mm across. All three pieces embedded in one block.

MICROSCOPIC REPORT

1. "LEFT AXILLARY CONTENTS".

The metastatic tumour consist of large cohesive masses of pleomorphic epithelioid and spindle cells. Staining is strongly positive for S100, HMB45 and Melan-A but shows only very weak, focal, probably aberrant staining for cytokeratin, consistent with melanoma. Metastatic melanoma is present in the large macroscopically involved lymph node. There is no extranodal spread. A further fragment of tumour and lymph node is present in block J but this appears to be a detached fragment of the larger node rather than a complete small lymph node. The remaining 25 lymph nodes are negative for malignancy.

2. "APICAL NODE LEFT AXILLA".

The specimen contains three lymph nodes, negative for malignancy.

A UN10

This fax was received b.

[page 2 of 2]
Requested by:

MRN/Na
Locati...
Accession:**HISTOPATHOLOGY REPORT****SUMMARY**

LEFT AXILLARY LYMPH NODE DISSECTION - METASTATIC MELANOMA PRESENT IN 1 OF 29
NODES.

REPORTED BY: Dr

A Unit of

Printed

Page 2 of 2

This fax was received by /

Source: NCI Genomic Data Commons file 0cff839f-d836-44f1-98c5-90969120b8cc (TCGA-EE-A29M.62B8E490-9790-4D86-93B4-24AE7F909A32.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).